Somatic mutation profile of tumor specimen HCM-BROD-0710-C43-06C (aliquot HCM-BROD-0710-C43-06C-11D-A881-36) from HCMI case HCM-BROD-0710-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.1 years (25,595 days).
Specimen HCM-BROD-0710-C43-06C: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b65ef5a-6ddb-4598-a90f-424beac5dc63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0710-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0710-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88b61876-5136-4fc2-8fb2-518c59ba7a49

The open-access MAF lists 277 somatic variants for this specimen: 181 protein-altering or splice-affecting, 85 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 85, Nonsense Mutation 14, 5'Flank 4, Frame Shift Ins 3, 3'UTR 2, Intron 2, 5'UTR 1, Frame Shift Del 1, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.4294C>T p.R1432* | Nonsense Mutation (SNP) | VAF 70/413 reads (17%) | catalogued as rs587779585, CM013250, COSV58591606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.291-1G>A p.X97_splice | Splice Site (SNP) | VAF 60/310 reads (19%) | hotspot (GDC flag); catalogued as rs112675807, CS004815, CS147061, CS982372, COSV58820323; called by muse, mutect2, varscan2
- ABL2 | c.2017C>T p.R673* (on ENST00000502732 / NM_007314.4; = p.R658* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 104/644 reads (16%) | catalogued as rs374429546; called by muse, mutect2, varscan2
- ADGRA2 | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 127/728 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs774085335; called by muse, mutect2, varscan2
- AKR1B15 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs866009184, COSV71152976; called by muse, mutect2, varscan2
- ALOX12B | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as COSV59876071; called by muse, mutect2, varscan2
- ANKRD30A | c.2845G>A p.D949N (on ENST00000611781; = p.D893N on NM_052997.2) | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64622909; called by muse, mutect2
- ARL3 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs751601468; called by muse, mutect2, varscan2
- ASIC5 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 73/431 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV73332547; called by muse, mutect2, varscan2
- ATXN7L2 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 96/623 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs772939744, COSV60205175; called by muse, mutect2, varscan2
- BACH1 | c.1813C>A p.H605N | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV54519123; called by mutect2, varscan2
- BCAM | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 108/539 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs569668745, COSV54304706; called by muse, mutect2, varscan2
- BEND3 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 84/500 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782353671; called by muse, mutect2, varscan2
- BSDC1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 118/601 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs201994378; called by muse, mutect2, varscan2
- C19orf47 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs773570067; called by muse, mutect2, varscan2
- CASR | c.1922G>A p.W641* (on ENST00000490131; = p.W718* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 94/703 reads (13%) | catalogued as COSV56136686; called by muse, mutect2, varscan2
- CBLL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 86/602 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs868368528, COSV60370252; called by muse, mutect2, varscan2
- CHD4 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as rs762788560; called by muse, mutect2, varscan2
- CMYA5 | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV71404083; called by muse, mutect2, varscan2
- COL23A1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 57/374 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs373742794; called by muse, mutect2, varscan2
- CPXCR1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 123/595 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52162894; called by muse, mutect2, varscan2
- DACT2 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 80/478 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV64693187; called by muse, mutect2, varscan2
- DRD1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 45/409 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.062); catalogued as rs1410757996, COSV67104610; called by muse, mutect2, varscan2
- DSEL | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 76/486 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as COSV59489992; called by muse, mutect2, varscan2
- EIF4E1B | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 71/483 reads (15%) | catalogued as rs1342984580; called by muse, mutect2, varscan2
- FADS6 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 89/524 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs145096183, COSV59601801; called by muse, mutect2, varscan2
- FBXO40 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV57526473; called by muse, mutect2, varscan2
- FNTB | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212071241, COSV55760527; called by muse, mutect2, varscan2
- FYB2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 35/307 reads (11%) | catalogued as COSV58583196; called by muse, mutect2, varscan2
- GABRA6 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770297519; called by muse, mutect2, varscan2
- GGT7 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 79/490 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs569819094; called by muse, mutect2, varscan2
- GHSR | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 68/546 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.147); catalogued as COSV53841545; called by muse, mutect2, varscan2
- GIPC1 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 108/683 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374322460; called by muse, mutect2, varscan2
- GOLGA4 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs755889799, COSV100728646; called by muse, mutect2, varscan2
- HHLA2 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 117/724 reads (16%) | catalogued as rs1272904239, COSV63320800; called by muse, mutect2, varscan2
- JAK2 | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774138621, COSV67674921; called by muse, mutect2, varscan2
- JAK2 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777259241; called by muse, mutect2, varscan2
- JCAD | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 91/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64757950; called by muse, mutect2, varscan2
- KCNB2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 95/584 reads (16%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.049); catalogued as COSV73050366; called by muse, mutect2, varscan2
- KIF18A | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV54185320; called by muse, mutect2, varscan2
- KMT2D | c.9851C>T p.S3284F | Missense Mutation (SNP) | VAF 109/644 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56447565; called by muse, mutect2, varscan2
- KRT14 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 73/503 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs773622623, COSV99390973; called by muse, varscan2
- LCE6A | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 63/367 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs938993602; called by muse, mutect2, varscan2
- LIPI | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated (0.52); PolyPhen probably damaging (1); catalogued as COSV60715612; called by muse, mutect2, varscan2
- LMBR1L | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV57268612; called by muse, mutect2, varscan2
- LRRIQ1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376422827, COSV101280677; called by muse, mutect2, varscan2
- MAP3K10 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 135/757 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1333936673, COSV53421523; called by muse, mutect2, varscan2
- MAST4 | c.4190C>A p.S1397Y (on ENST00000403625 / NM_001164664.2; = p.S1208Y on NM_015183.3) | Missense Mutation (SNP) | VAF 122/775 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55115217; called by muse, mutect2, varscan2
- ME1 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100866467; called by muse, mutect2, varscan2
- METTL25 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763803362, COSV50259150; called by muse, mutect2, varscan2
- MOV10L1 | c.3086G>A p.G1029E | Missense Mutation (SNP) | VAF 79/459 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99433565; called by muse, mutect2, varscan2
- MRAP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57632375; called by muse, mutect2, varscan2
- MYH7 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 123/778 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs730880820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV51784348; called by muse, mutect2, varscan2
- MYO18B | c.3868G>A p.G1290R | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV59129637; called by muse, mutect2, varscan2
- NCAM1 | c.1711G>A p.V571I (on ENST00000316851 / NM_181351.5; = p.V561I on NM_000615.7) | Missense Mutation (SNP) | VAF 66/403 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs370003415, COSV57520141; called by muse, mutect2, varscan2
- NCOR1 | c.2820G>A p.M940I | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.885); catalogued as rs773195986; called by muse, mutect2, varscan2
- NFE2L2 | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67960328; called by muse, mutect2, varscan2
- NLRP4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs1175246779, COSV56709262, COSV56719853; called by muse, mutect2, varscan2
- NPHP3 | c.3299G>A p.G1100D | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758927671; called by muse, mutect2, varscan2
- OR10A7 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 93/526 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760505741; called by muse, varscan2
- OR12D3 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 89/644 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780883178, COSV101011422; called by muse, mutect2, varscan2
- OR13C5 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 134/454 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778754351, COSV66164157; called by muse, mutect2, varscan2
- OR1A1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1029042752, COSV58403574; called by muse, mutect2, varscan2
- OR2L5 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 71/403 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs766169928, COSV62364235; called by muse, mutect2, varscan2
- OR4C12 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1555019990; called by muse, mutect2, varscan2
- OR4N2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60050301; called by muse, mutect2
- OR51D1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 90/536 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1473413857, COSV62914851; called by muse, mutect2, varscan2
- OR51I1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 94/534 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs373885594; called by muse, mutect2
- OR5C1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 121/833 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65456042; called by muse, mutect2, varscan2
- OR5K3 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs923664547; called by muse, mutect2, varscan2
- PAPPA2 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 112/572 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs1192409900; called by muse, mutect2, varscan2
- PDGFB | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 79/515 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as COSV58649360; called by muse, mutect2, varscan2
- PLA2G4D | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 105/539 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV51820833; called by muse, mutect2, varscan2
- PTPRC | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV61419376; called by muse, mutect2, varscan2
- PUSL1 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs779407926; called by muse, mutect2, varscan2
- PWWP3B | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 122/614 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61798632; called by muse, mutect2, varscan2
- PYGO1 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100114628; called by muse, mutect2, varscan2
- RERE | c.4106C>T p.P1369L | Missense Mutation (SNP) | VAF 106/638 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs1233073978; called by muse, varscan2
- RIMS2 | c.3806G>A p.G1269E | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs537701932, COSV51678947; called by muse, mutect2, varscan2
- RNF212 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs993885644; called by muse, mutect2, varscan2
- SCN11A | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571721216, COSV56565730; called by muse, mutect2, varscan2
- SCYL1 | c.1233C>T p.S411= | Splice Region (SNP) | VAF 74/392 reads (19%) | catalogued as rs377590378; called by muse, mutect2, varscan2
- SETX | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 152/581 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1286335620; called by muse, mutect2, varscan2
- SHANK2 | c.4535C>T p.T1512I | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53619418; called by muse, mutect2, varscan2
- SLC30A10 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 72/479 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63070770; called by muse, mutect2, varscan2
- SLC6A11 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs757265540, COSV54397819; called by muse, mutect2, varscan2
- SLC9A4 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 109/650 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181947037; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 96/473 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100561681; called by muse, mutect2, varscan2
- SYT16 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV70856873; called by muse, mutect2, varscan2
- TGM2 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100821817; called by muse, mutect2, varscan2
- TNK2 | c.3028C>T p.H1010Y | Missense Mutation (SNP) | VAF 92/711 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as rs1163181869; called by muse, mutect2, varscan2
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 31/197 reads (16%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- TTN | c.10390G>A p.E3464K (on ENST00000591111; = p.E3418K on NM_003319.4) | Missense Mutation (SNP) | VAF 56/244 reads (23%) | catalogued as rs773793548, COSV59961451; called by muse, mutect2, varscan2
- TYW1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 85/541 reads (16%) | catalogued as rs769154282, COSV62753704; called by muse, mutect2, varscan2
- ZC3H12D | c.401del p.P134Hfs*51 | Frame Shift Del (DEL) | VAF 46/292 reads (16%) | catalogued as COSV66324648; called by mutect2, pindel*, varscan2
- ABCA8 | c.3018T>A p.D1006E | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABL1 | c.606T>A p.H202Q | Missense Mutation (SNP) | VAF 187/621 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ACMSD | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2067G>A p.W689* | Nonsense Mutation (SNP) | VAF 285/813 reads (35%) | called by muse, mutect2, varscan2
- BEGAIN | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 171/849 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BUB1B | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C13orf42 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 60/396 reads (15%) | called by muse, mutect2, varscan2
- CBX6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 135/695 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD40 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH10 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CEP126 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CHD4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- COL4A2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 69/472 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.107); called by muse, mutect2
- COL5A2 | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 55/361 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CROCC2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 83/550 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DENND2C | c.2177C>A p.P726Q (on ENST00000393274 / NM_001256404.2; = p.P669Q on NM_198459.4) | Missense Mutation (SNP) | VAF 105/490 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHBP1L1 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 71/473 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM234B | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 87/590 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FRK | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCB | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- GGT7 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 80/490 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- GMNC | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 69/447 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPRC6A | c.2556G>A p.M852I | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HADHA | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- HECTD4 | c.12554C>T p.A4185V | Missense Mutation (SNP) | VAF 87/496 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HMX1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 96/772 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.118); called by mutect2, varscan2
- INSRR | c.3139G>A p.G1047S | Missense Mutation (SNP) | VAF 75/432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- JCAD | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 109/681 reads (16%) | called by muse, mutect2, varscan2
- KLF15 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 155/521 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KMT5B | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 79/549 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT5B | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 79/545 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRN3 | c.1877C>T p.T626I | Missense Mutation (SNP) | VAF 69/419 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCF2 | c.612_613insA p.G205Rfs*20 | Frame Shift Ins (INS) | VAF 51/404 reads (13%) | called by mutect2, pindel, varscan2
- MORC1 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 97/379 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MUC17 | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 86/1068 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2
- MYO10 | c.1474T>A p.C492S | Missense Mutation (SNP) | VAF 67/389 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO15A | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NAB1 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRXN1 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 71/523 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.2003T>G p.V668G | Missense Mutation (SNP) | VAF 89/571 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NXF3 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 102/669 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OBSCN | c.15511C>T p.H5171Y | Missense Mutation (SNP) | VAF 125/598 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR52J3 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OTOG | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 114/536 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PAPPA2 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 114/573 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGAP1 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PLCB2 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PLCH2 | c.4226A>T p.E1409V | Missense Mutation (SNP) | VAF 91/618 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLEKHG3 | c.1073C>T p.S358F (on ENST00000394691; = p.S414F on NM_001308147.2) | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PRDM11 | c.946C>T p.P316S (on ENST00000530656 / NM_001359633.1; = p.P282S on NM_001256695.1) | Missense Mutation (SNP) | VAF 67/490 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRR23D1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 52/939 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.646); called by muse, mutect2
- PSMD1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- RAB11FIP1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RASAL3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 57/478 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- RSRP1 | c.550dup p.T184Nfs*13 | Frame Shift Ins (INS) | VAF 64/386 reads (17%) | called by mutect2, pindel, varscan2
- RXRA | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 213/782 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RYR2 | c.4300C>T p.P1434S | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SCARF2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 107/540 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCEL | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SETD2 | c.6479dup p.H2161Afs*23 | Frame Shift Ins (INS) | VAF 194/777 reads (25%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 150/744 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLU7 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 77/412 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SMIM23 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 75/525 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORL1 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SSRP1 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 90/519 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SYT16 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- THEMIS2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR4 | c.2093A>T p.E698V (on ENST00000355622 / NM_138554.5; = p.E658V on NM_003266.4) | Missense Mutation (SNP) | VAF 191/665 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- TMC8 | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 127/800 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM209 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TNFSF13B | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRIML2 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 56/471 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TTN | c.57988G>A p.E19330K (on ENST00000591111; = p.E11906K on NM_003319.4) | Missense Mutation (SNP) | VAF 100/569 reads (18%) | PolyPhen benign (0.254); called by muse, mutect2, varscan2
- USP34 | c.8526T>G p.D2842E | Missense Mutation (SNP) | VAF 89/534 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP34 | c.5146A>T p.I1716F | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP35 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VCAN | c.8979G>A p.W2993* | Nonsense Mutation (SNP) | VAF 78/502 reads (16%) | called by muse, mutect2, varscan2
- WASHC2A | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- WDR87 | c.7322G>A p.G2441E | Missense Mutation (SNP) | VAF 89/521 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE26 | c.3295G>T p.E1099* | Nonsense Mutation (SNP) | VAF 50/309 reads (16%) | called by muse, mutect2, varscan2
- ZMYM4 | c.3193C>T p.Q1065* | Nonsense Mutation (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- ZNF367 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 127/417 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF74 | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 130/732 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ABCA13 | c.14586G>A p.K4862= | Silent (SNP) | VAF 87/511 reads (17%) | called by muse, mutect2, varscan2
- ABL2 | c.2016C>T p.F672= (on ENST00000502732 / NM_007314.4; = p.F657= on NM_005158.5) | Silent (SNP) | VAF 104/645 reads (16%) | catalogued as rs867406798; called by muse, mutect2, varscan2
- ADAM19 | c.1719G>A p.G573= | Silent (SNP) | VAF 76/444 reads (17%) | catalogued as COSV57432464; called by muse, mutect2, varscan2
- ADAM33 | c.2304C>T p.P768= | Silent (SNP) | VAF 88/665 reads (13%) | called by muse, mutect2
- ADAM7 | c.954C>T p.I318= | Silent (SNP) | VAF 60/440 reads (14%) | catalogued as COSV51545823, COSV99442708; called by muse, mutect2, varscan2
- ADGRB2 | c.2037G>A p.E679= | Silent (SNP) | VAF 95/465 reads (20%) | catalogued as COSV57076300; called by muse, mutect2, varscan2
- ADGRV1 | c.9021G>A p.L3007= | Silent (SNP) | VAF 56/290 reads (19%) | called by muse, mutect2, varscan2
- ALG10 | c.637C>T p.L213= | Silent (SNP) | VAF 67/470 reads (14%) | catalogued as rs1277639824; called by muse, mutect2, varscan2
- ALOX12B | c.621G>A p.T207= | Silent (SNP) | VAF 50/278 reads (18%) | catalogued as COSV59874227; called by muse, mutect2, varscan2
- BTBD11 | c.2496C>T p.I832= (on ENST00000280758 / NM_001018072.2; = p.I369= on NM_001017523.2) | Silent (SNP) | VAF 81/491 reads (16%) | catalogued as rs758128980, COSV55024804; called by muse, varscan2
- BUB1B | c.2637C>T p.V879= | Silent (SNP) | VAF 56/381 reads (15%) | called by muse, mutect2, varscan2
- C17orf80 | c.396C>T p.F132= | Silent (SNP) | VAF 44/316 reads (14%) | called by muse, mutect2, varscan2
- C1QTNF12 | c.156G>A p.E52= | Silent (SNP) | VAF 86/650 reads (13%) | called by muse, mutect2, varscan2
- CARD11 | c.2577C>T p.D859= | Silent (SNP) | VAF 105/623 reads (17%) | catalogued as rs140815848, COSV62755416; called by muse, mutect2, varscan2
- CBX6 | c.1080C>T p.P360= | Silent (SNP) | VAF 134/694 reads (19%) | catalogued as rs895128516; called by muse, mutect2, varscan2
- CD1A | c.906C>T p.F302= | Silent (SNP) | VAF 80/462 reads (17%) | catalogued as rs1318762759, COSV56861264; called by muse, mutect2, varscan2
- CEP162 | c.3840T>A p.S1280= | Silent (SNP) | VAF 49/302 reads (16%) | called by muse, mutect2, varscan2
- CHN1 | c.870G>A p.R290= | Silent (SNP) | VAF 67/360 reads (19%) | catalogued as rs1292344281; called by muse, mutect2, varscan2
- CNTNAP5 | c.1482C>A p.P494= | Silent (SNP) | VAF 72/360 reads (20%) | catalogued as COSV70490746; called by muse, mutect2, varscan2
- COL4A6 | c.4887G>A p.R1629= | Silent (SNP) | VAF 118/825 reads (14%) | catalogued as COSV100564773; called by muse, mutect2, varscan2
- DAPK1 | c.3393C>T p.I1131= | Silent (SNP) | VAF 116/734 reads (16%) | catalogued as rs765353398, COSV63786799; called by muse, mutect2, varscan2
- DNAH7 | c.8937A>T p.I2979= | Silent (SNP) | VAF 43/247 reads (17%) | called by muse, mutect2, varscan2
- DPF2 | c.489C>T p.F163= | Silent (SNP) | VAF 82/444 reads (18%) | catalogued as rs1420017796; called by muse, mutect2, varscan2
- DSCAM | c.327G>A p.G109= | Silent (SNP) | VAF 59/362 reads (16%) | catalogued as COSV68638075; called by muse, mutect2, varscan2
- ERO1A | c.1033C>T p.L345= | Silent (SNP) | VAF 41/211 reads (19%) | called by muse, mutect2, varscan2
- FADS3 | c.723C>T p.F241= | Silent (SNP) | VAF 54/329 reads (16%) | catalogued as COSV53877663; called by muse, mutect2, varscan2
- FAM160B2 | c.1515C>T p.T505= | Silent (SNP) | VAF 86/481 reads (18%) | catalogued as rs371113614; called by muse, mutect2, varscan2
- FAM47C | c.114G>A p.L38= | Silent (SNP) | VAF 107/715 reads (15%) | catalogued as COSV63726479; called by muse, mutect2, varscan2
- FAT3 | c.882G>A p.A294= | Silent (SNP) | VAF 63/468 reads (13%) | catalogued as rs200428460, COSV53121432; called by muse, mutect2, varscan2
- FER1L6 | c.5523C>T p.F1841= | Silent (SNP) | VAF 164/555 reads (30%) | catalogued as COSV67550086; called by muse, varscan2
- FLT1 | c.165G>A p.G55= | Silent (SNP) | VAF 56/393 reads (14%) | catalogued as rs1309467103; called by muse, mutect2, varscan2
- FSD2 | c.963A>T p.I321= | Silent (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
- GDE1 | c.462C>T p.I154= | Silent (SNP) | VAF 51/359 reads (14%) | called by muse, mutect2, varscan2
- GPX2 | c.135G>A p.R45= | Silent (SNP) | VAF 67/399 reads (17%) | catalogued as rs772907040; called by muse, mutect2, varscan2
- GRIA2 | c.1779G>A p.G593= | Silent (SNP) | VAF 54/364 reads (15%) | catalogued as COSV52390550, COSV52392955; called by muse, mutect2, varscan2
- GRK1 | c.513C>T p.F171= | Silent (SNP) | VAF 75/564 reads (13%) | catalogued as rs1470677060, COSV59553636; called by muse, mutect2, varscan2
- HEPHL1 | c.1707T>C p.D569= | Silent (SNP) | VAF 29/292 reads (10%) | called by muse, mutect2, varscan2
- IGF2R | c.1335T>G p.T445= | Silent (SNP) | VAF 57/333 reads (17%) | called by muse, mutect2
- LAMA1 | c.8628G>A p.P2876= | Silent (SNP) | VAF 84/530 reads (16%) | catalogued as rs547747946; called by muse, mutect2, varscan2
- LCT | c.3834G>A p.L1278= | Silent (SNP) | VAF 90/518 reads (17%) | catalogued as COSV51547126; called by muse, mutect2, varscan2
- MAPKAP1 | c.870C>T p.S290= | Silent (SNP) | VAF 118/385 reads (31%) | called by muse, mutect2, varscan2
- MBIP | c.300T>C p.A100= | Silent (SNP) | VAF 50/360 reads (14%) | called by muse, mutect2, varscan2
- MTRNR2L7 | c.69G>A p.Q23= | Silent (SNP) | VAF 58/366 reads (16%) | called by muse, mutect2
- MUC16 | c.38475C>T p.T12825= | Silent (SNP) | VAF 88/303 reads (29%) | called by muse, mutect2, varscan2
- MUC3A | c.8067C>T p.I2689= | Silent (SNP) | VAF 78/1099 reads (7%) | catalogued as COSV60222520; called by muse, mutect2
- MYOCD | c.1446C>T p.F482= | Silent (SNP) | VAF 117/579 reads (20%) | catalogued as rs747325331; called by muse, mutect2, varscan2
- NUTM2G | c.60C>T p.T20= | Silent (SNP) | VAF 71/475 reads (15%) | called by muse, mutect2, varscan2
- OR2L3 | c.180C>T p.F60= | Silent (SNP) | VAF 71/525 reads (14%) | catalogued as COSV63454535; called by muse, mutect2, varscan2
- OR4D9 | c.90C>T p.F30= | Silent (SNP) | VAF 79/500 reads (16%) | called by muse, mutect2, varscan2
- OR51D1 | c.126C>T p.F42= | Silent (SNP) | VAF 84/592 reads (14%) | catalogued as rs1031689978; called by muse, mutect2, varscan2
- OR5BS1P | c.186C>T p.F62= | Silent (SNP) | VAF 90/583 reads (15%) | called by muse, mutect2, varscan2
- PACS1 | c.1419G>A p.L473= | Silent (SNP) | VAF 91/491 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1965C>T p.S655= | Silent (SNP) | VAF 133/993 reads (13%) | catalogued as rs771072942, COSV99541905; called by muse, mutect2, varscan2
- PDXDC1 | c.1788C>T p.A596= | Silent (SNP) | VAF 81/514 reads (16%) | called by muse, mutect2, varscan2
- PIK3C2G | c.360G>A p.T120= | Silent (SNP) | VAF 82/484 reads (17%) | catalogued as rs1342910617; called by muse, mutect2, varscan2
- PLEKHM3 | c.2133C>T p.F711= | Silent (SNP) | VAF 50/416 reads (12%) | called by muse, mutect2
- PPP2R3B | c.117C>T p.I39= | Silent (SNP) | VAF 182/953 reads (19%) | called by muse, mutect2, varscan2
- PRKD3 | c.2244C>T p.L748= | Silent (SNP) | VAF 96/497 reads (19%) | called by muse, mutect2, varscan2
- PRR23C | c.588G>A p.G196= | Silent (SNP) | VAF 188/655 reads (29%) | catalogued as rs1278649469, COSV101356490; called by muse, mutect2, varscan2
- PTGS2 | c.84C>T p.N28= | Silent (SNP) | VAF 63/324 reads (19%) | catalogued as rs1366501556; called by muse, mutect2, varscan2
- PTPN13 | c.1527C>T p.I509= | Silent (SNP) | VAF 61/426 reads (14%) | catalogued as COSV57401681; called by muse, mutect2, varscan2
- RBBP8NL | c.798C>T p.F266= | Silent (SNP) | VAF 63/344 reads (18%) | catalogued as rs1358698882; called by muse, mutect2, varscan2
- RNF20 | c.996T>C p.L332= | Silent (SNP) | VAF 63/394 reads (16%) | called by muse, mutect2, varscan2
- SALL1 | c.849C>T p.S283= | Silent (SNP) | VAF 85/509 reads (17%) | catalogued as COSV51756097; called by muse, mutect2, varscan2
- SEMA3G | c.234C>A p.L78= | Silent (SNP) | VAF 167/667 reads (25%) | called by muse, mutect2, varscan2
- SEMA7A | c.624C>T p.G208= | Silent (SNP) | VAF 82/535 reads (15%) | catalogued as rs369347333; called by muse, mutect2, varscan2
- SERPINI1 | c.897G>A p.Q299= | Silent (SNP) | VAF 93/321 reads (29%) | called by muse, mutect2, varscan2
- SETX | c.438C>T p.S146= | Silent (SNP) | VAF 152/584 reads (26%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.249C>T p.N83= | Silent (SNP) | VAF 84/556 reads (15%) | catalogued as rs1568516190; called by muse, mutect2, varscan2
- SKAP1 | c.747C>T p.P249= | Silent (SNP) | VAF 89/569 reads (16%) | called by muse, mutect2, varscan2
- SLC10A2 | c.219C>T p.L73= | Silent (SNP) | VAF 104/554 reads (19%) | catalogued as COSV99807656; called by muse, mutect2, varscan2
- SMYD1 | c.420G>A p.G140= | Silent (SNP) | VAF 113/617 reads (18%) | called by muse, mutect2, varscan2
- SMYD2 | c.492C>T p.L164= | Silent (SNP) | VAF 67/459 reads (15%) | catalogued as rs770920046; called by muse, mutect2, varscan2
- SNAP91 | c.1485C>T p.L495= | Silent (SNP) | VAF 85/498 reads (17%) | called by muse, mutect2, varscan2
- SPEF2 | c.4992C>T p.S1664= | Silent (SNP) | VAF 50/306 reads (16%) | called by muse, mutect2, varscan2
- SVEP1 | c.939G>A p.G313= | Silent (SNP) | VAF 73/523 reads (14%) | called by muse, mutect2, varscan2
- TENM3 | c.9G>A p.V3= | Silent (SNP) | VAF 56/243 reads (23%) | catalogued as COSV101305334; called by muse, mutect2, varscan2
- TMCC3 | c.1341T>C p.L447= | Silent (SNP) | VAF 76/511 reads (15%) | called by muse, mutect2, varscan2
- TMIGD1 | c.417G>A p.V139= | Silent (SNP) | VAF 66/350 reads (19%) | called by muse, mutect2, varscan2
- TRPC7 | c.1491G>A p.T497= | Silent (SNP) | VAF 94/600 reads (16%) | catalogued as rs1272174809; called by muse, mutect2, varscan2
- VPS35L | c.2763G>A p.Q921= | Silent (SNP) | VAF 56/380 reads (15%) | catalogued as rs777311864; called by muse, mutect2, varscan2
- WASHC2A | c.1146C>T p.P382= | Silent (SNP) | VAF 43/219 reads (20%) | catalogued as rs1451463455; called by muse, mutect2, varscan2
- WDR64 | c.3027C>T p.F1009= | Silent (SNP) | VAF 52/453 reads (11%) | catalogued as rs749470958; called by muse, mutect2, varscan2
- ZFHX4 | c.6429C>T p.I2143= | Silent (SNP) | VAF 51/350 reads (15%) | catalogued as COSV50495484; called by muse, mutect2, varscan2
- ZNF430 | c.606G>A p.K202= | Silent (SNP) | VAF 76/267 reads (28%) | catalogued as COSV99842068; called by muse, mutect2, varscan2
- ABTB1 | c.*299C>T | 3'UTR (SNP) | VAF 163/636 reads (26%) | catalogued as rs773878210; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915174 C>T | 5'Flank (SNP) | VAF 72/501 reads (14%) | catalogued as rs762491934, COSV58124328; called by muse, mutect2, varscan2
- C4orf50 | c.-53C>T | 5'UTR (SNP) | VAF 36/456 reads (8%) | called by muse, mutect2
- C4orf50 | chr4:5990198 G>A | 5'Flank (SNP) | VAF 68/365 reads (19%) | catalogued as rs1426995796; called by muse, mutect2, varscan2
- CLASP1 | chr2:121649899 C>T | 5'Flank (SNP) | VAF 74/467 reads (16%) | called by muse, mutect2, varscan2
- LTN1 | chr21:28992921 T>C | 5'Flank (SNP) | VAF 76/425 reads (18%) | called by muse, mutect2, varscan2
- NEBL | c.164+46321G>A | Intron (SNP) | VAF 87/506 reads (17%) | called by muse, mutect2, varscan2
- NPAP1L | n.449C>T | RNA (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- PUDP | c.511-7298G>A | Intron (SNP) | VAF 113/571 reads (20%) | called by muse, mutect2, varscan2
- SLC9A3 | c.*225G>A | 3'UTR (SNP) | VAF 129/530 reads (24%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672741 G>A | 3'Flank (SNP) | VAF 81/503 reads (16%) | called by muse, mutect2, varscan2
